Somatic mutation profile of tumor specimen TCGA-AA-3845-01A (aliquot TCGA-AA-3845-01A-01D-1981-10) from TCGA case TCGA-AA-3845, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 86.5 years (31,593 days).
Specimen TCGA-AA-3845-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c783cbb5-772f-4554-886d-04fb3173eed8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3845-10A (Blood Derived Normal), aliquot TCGA-AA-3845-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17c378f3-86a7-4245-af7e-0c2d4dd75216

The open-access MAF lists 1,194 somatic variants for this specimen: 922 protein-altering or splice-affecting, 247 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 638, Silent 247, Frame Shift Del 178, Nonsense Mutation 39, Frame Shift Ins 29, Splice Site 14, In Frame Del 14, Intron 11, Splice Region 9, 3'UTR 5, RNA 4, 5'Flank 3.

Variants (750 of 1,194; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG6 | c.1194del p.F398Lfs*2 | Frame Shift Del (DEL) | VAF 49/194 reads (25%) | catalogued as rs1207096732; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 72/247 reads (29%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL5A1 | c.1502del p.P501Lfs*57 | Frame Shift Del (DEL) | VAF 45/153 reads (29%) | catalogued as rs1085307855; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ETV6 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 42/84 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1511682, COSV56765384, COSV56765583; called by muse, mutect2, varscan2
- FERMT1 | c.676del p.Q226Sfs*26 | Frame Shift Del (DEL) | VAF 55/247 reads (22%) | catalogued as rs748240859, COSV54090339; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 84/345 reads (24%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KLHL40 | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367579275, CM136546; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 50/138 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: pathogenic; called by muse, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 116/416 reads (28%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- POLR3GL | c.326-1G>A p.X109_splice | Splice Site (SNP) | VAF 37/128 reads (29%) | catalogued as rs1553763618, COSV100996784; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC18A2 | c.711del p.F238Sfs*48 | Frame Shift Del (DEL) | VAF 38/170 reads (22%) | catalogued as rs762879329, COSV53693545; ClinVar: likely pathogenic; called by mutect2, pindel
- SMAD4 | c.1598T>G p.L533R | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377767382, CM040451, CM100521, COSV61684983, COSV61685664; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.59765del p.P19922Lfs*10 (on ENST00000591111; = p.P12498Lfs*10 on NM_003319.4) | Frame Shift Del (DEL) | VAF 19/81 reads (23%) | catalogued as rs774395395, COSV99045840; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by pindel, varscan2
- VHL | c.444del p.F148Lfs*11 | Frame Shift Del (DEL) | VAF 75/272 reads (28%) | catalogued as rs869025653, CM982009; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.1624A>G p.S542G | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.042); catalogued as COSV100228866; called by muse, mutect2, varscan2
- ABAT | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as rs150783272; called by muse, mutect2, varscan2
- ABCA6 | c.4817T>C p.M1606T | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs751793678, COSV99446348; called by muse, mutect2, varscan2
- ABCC10 | c.1983del p.L662Cfs*38 (on ENST00000372530 / NM_001198934.2; = p.L634Cfs*38 on NM_033450.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | catalogued as COSV55091561; called by mutect2, pindel, varscan2
- ABHD6 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.439); catalogued as COSV99917008; called by muse, mutect2, varscan2
- ABLIM2 | c.1405del p.D469Mfs*94 (on ENST00000341937 / NM_001130084.2; = p.D418Mfs*55 on NM_032432.5) | Frame Shift Del (DEL) | VAF 41/154 reads (27%) | catalogued as COSV56411246; called by mutect2, pindel, varscan2
- ABLIM2 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99589535; called by muse, mutect2, varscan2
- ACKR2 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs748142680, COSV99825494; called by muse, mutect2, varscan2
- ACSL3 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs748604442, COSV100657925; called by muse, mutect2, varscan2
- ACTN1 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs373084944; called by mutect2, varscan2
- ACVR2A | c.1080T>C p.V360= | Splice Region (SNP) | VAF 65/252 reads (26%) | catalogued as COSV99604412; called by muse, mutect2, varscan2
- ADAM18 | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 73/253 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); catalogued as COSV99695460; called by muse, mutect2, varscan2
- ADAMTS2 | c.3268T>C p.C1090R | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99281955; called by muse, mutect2, varscan2
- ADAMTS20 | c.4913C>A p.P1638H | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101239197, COSV67141911; called by muse, mutect2, varscan2
- ADAMTS20 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs765553839, COSV101239198; called by muse, mutect2, varscan2
- ADCK1 | c.1400+2T>C p.X467_splice | Splice Site (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99451582; called by muse, mutect2
- ADCY2 | c.1412G>T p.R471L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100602683; called by muse, mutect2, varscan2
- ADGRA2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs777378349; called by muse, varscan2
- AFF3 | c.2987A>G p.E996G | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100418692; called by muse, mutect2, varscan2
- AGO2 | c.2063G>A p.R688H | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99595649; called by muse, mutect2, varscan2
- AHNAK2 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.742); catalogued as rs200025024, COSV60917709; called by muse, mutect2, varscan2
- AIPL1 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145112457, COSV100006040; called by muse, mutect2, varscan2
- AK7 | c.472T>C p.W158R | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99967219; called by muse, mutect2, varscan2
- AKAP10 | c.1401G>T p.R467S | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99855413; called by muse, mutect2, varscan2
- ALDH18A1 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs760865106, COSV64662802; called by muse, mutect2, varscan2
- ALDH8A1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs755934699, COSV99664666; called by muse, mutect2, varscan2
- ALDOB | c.482G>T p.S161I | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.095); catalogued as COSV100878854; called by muse, mutect2, varscan2
- ALK | c.1647G>T p.E549D | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.396); catalogued as COSV101201896; called by muse, mutect2, varscan2
- ALMS1 | c.12114G>T p.Q4038H | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100042226; called by muse, mutect2, varscan2
- ALPK3 | c.4441T>C p.Y1481H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99360778; called by muse, mutect2, varscan2
- ALS2 | c.4808C>T p.P1603L | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99968734, COSV99969217; called by muse, mutect2, varscan2
- ANKRD44 | c.1919C>A p.A640D | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99984858; called by muse, mutect2, varscan2
- ANKRD45 | c.284C>A p.A95D | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV100322475; called by muse, mutect2, varscan2
- ANPEP | c.2098A>C p.S700R | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV100262984; called by muse, mutect2, varscan2
- ANTXR1 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV58015869; called by muse, mutect2, varscan2
- APMAP | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs181867455, COSV99468412; called by muse, varscan2
- APPL1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.568); catalogued as rs753038546, COSV55700704; called by muse, mutect2, varscan2
- ARAP2 | c.3309G>A p.W1103* | Nonsense Mutation (SNP) | VAF 68/214 reads (32%) | catalogued as rs866438657, COSV100394548; called by muse, mutect2, varscan2
- ARFGEF2 | c.3290T>C p.V1097A | Missense Mutation (SNP) | VAF 36/980 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV64214084; called by muse, mutect2
- ARHGAP24 | c.1037A>T p.N346I (on ENST00000395184 / NM_001025616.3; = p.N253I on NM_031305.3) | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.564); catalogued as COSV99982034; called by muse, mutect2, varscan2
- ARHGAP31 | c.2521C>A p.P841T | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV99957009; called by muse, mutect2, varscan2
- ARHGAP5 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 82/294 reads (28%) | catalogued as rs765717212, COSV100565239; called by muse, mutect2, varscan2
- ARHGEF2 | c.640G>A p.A214T (on ENST00000361247 / NM_001162383.2; = p.A186T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100560502; called by muse, mutect2, varscan2
- ARHGEF5 | c.2684G>A p.R895H | Missense Mutation (SNP) | VAF 40/289 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as rs769704083; called by muse, varscan2
- ARID2 | c.109del p.I37Sfs*21 | Frame Shift Del (DEL) | VAF 27/219 reads (12%) | catalogued as COSV57601825; called by mutect2, pindel, varscan2
- ARL11 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs1394373519, COSV56290674; called by muse, mutect2, varscan2
- ARMC3 | c.2085G>T p.E695D | Missense Mutation (SNP) | VAF 28/527 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.565); catalogued as COSV99957960; called by muse, mutect2
- ARMC4 | c.3095G>A p.R1032H | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375622560; called by muse, mutect2, varscan2
- ARMC4 | c.2720A>G p.N907S | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.468); catalogued as COSV100536690; called by muse, mutect2, varscan2
- ARPC5 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV99664781; called by muse, mutect2, varscan2
- ARRDC1 | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV101004533; called by muse, mutect2, varscan2
- AS3MT | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 82/278 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as COSV100185686; called by muse, varscan2
- ASIC2 | c.555+1G>A p.X185_splice | Splice Site (SNP) | VAF 20/66 reads (30%) | catalogued as COSV100726275; called by muse, mutect2, varscan2
- ASPN | c.201del p.P68Hfs*24 | Frame Shift Del (DEL) | VAF 41/150 reads (27%) | catalogued as rs778526424; called by mutect2, pindel, varscan2
- ASPSCR1 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769048147, COSV60729533; called by muse, varscan2
- ATF7IP2 | c.635A>G p.K212R | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV100202599; called by muse, mutect2, varscan2
- ATP10B | c.3142G>A p.V1048I | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs540605471, COSV100514791; called by muse, mutect2, varscan2
- ATP1A4 | c.1048-1G>A p.X350_splice | Splice Site (SNP) | VAF 38/140 reads (27%) | catalogued as COSV100927524, COSV100927649; called by muse, mutect2, varscan2
- ATP2B2 | c.2551G>A p.V851I (on ENST00000352432; = p.V817I on NM_001683.5) | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs778120026, COSV59492636; called by muse, mutect2, varscan2
- BCL2L1 | c.647C>T p.T216M (on ENST00000307677 / NM_001317919.2; = p.T153M on NM_001191.4) | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.622); catalogued as rs1447088802, COSV56967574; called by muse, mutect2, varscan2
- BCR | c.2993T>C p.M998T | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.388); catalogued as COSV100006394; called by muse, mutect2, varscan2
- BMP10 | c.1034C>A p.P345H | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.432); catalogued as COSV99770386; called by muse, mutect2, varscan2
- BOC | c.2581G>A p.V861I | Missense Mutation (SNP) | VAF 96/329 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs148702312; called by muse, mutect2, varscan2
- BRD1 | c.2884G>A p.V962I (on ENST00000216267 / NM_001349940.1; = p.V1093I on NM_001304808.3) | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); catalogued as rs562289968, COSV99349649; called by muse, mutect2, varscan2
- BRD3 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57704065; called by muse, mutect2
- BTBD10 | c.996A>C p.E332D | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV99533545; called by muse, mutect2, varscan2
- BTRC | c.1780del p.R594Vfs*14 (on ENST00000370187 / NM_033637.4; = p.R558Vfs*14 on NM_003939.5) | Frame Shift Del (DEL) | VAF 74/309 reads (24%) | catalogued as rs774921343; called by mutect2, pindel, varscan2
- C2orf16 | c.5801G>A p.R1934H | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763254401, COSV62675961; called by muse, mutect2, varscan2
- C3orf38 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV59627722; called by muse, mutect2, varscan2
- C4orf50 | c.142C>T p.R48C (on ENST00000324058; = p.R1280C on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs768362868, COSV100135828; called by muse, varscan2
- CACNA1B | c.3217G>T p.D1073Y | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as rs1441288898, COSV99497004; called by muse, mutect2, varscan2
- CACNA1G | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.374); catalogued as COSV61729592; called by muse, mutect2, varscan2
- CACNA1I | c.3436G>A p.E1146K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100360057; called by muse, mutect2, varscan2
- CADM1 | c.187A>C p.S63R | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV100522576; called by muse, mutect2, varscan2
- CADPS | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs147087123; called by muse, mutect2, varscan2
- CAMTA2 | c.1930C>T p.R644* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as rs147496832; called by muse, mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as rs765105588; called by mutect2, varscan2
- CASQ2 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV99797408; called by muse, mutect2, varscan2
- CAVIN2 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); catalogued as COSV100414152; called by muse, mutect2, varscan2
- CCDC106 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV58272641; called by muse, mutect2, varscan2
- CCDC112 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 69/285 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV101100431; called by muse, mutect2, varscan2
- CCDC115 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV99383704; called by muse, mutect2, varscan2
- CCDC14 | c.1775T>G p.V592G (on ENST00000488653; = p.V544G on NM_022757.5) | Missense Mutation (SNP) | VAF 79/329 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100113149; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 54/178 reads (30%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 62/204 reads (30%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC30 | c.442del p.T148Lfs*6 (on ENST00000340612; = p.T105Lfs*6 on NM_001080850.3) | Frame Shift Del (DEL) | VAF 83/349 reads (24%) | catalogued as rs775731046; called by mutect2, pindel, varscan2
- CCDC34 | c.731del p.N244Mfs*28 | Frame Shift Del (DEL) | VAF 88/306 reads (29%) | catalogued as rs773019149; called by mutect2, varscan2
- CCDC57 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 36/118 reads (31%) | catalogued as rs551783755; called by muse, varscan2
- CCDC63 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.056); catalogued as rs776401462, COSV99960737; called by muse, mutect2, varscan2
- CCDC80 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99244707; called by muse, mutect2, varscan2
- CCDC81 | c.1000C>G p.Q334E (on ENST00000445632 / NM_001156474.2; = p.Q244E on NM_021827.4) | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as COSV99564265; called by muse, mutect2, varscan2
- CCDC88C | c.4993C>T p.P1665S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100484845; called by muse, mutect2, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | catalogued as rs765438623; called by mutect2, pindel, varscan2
- CCN4 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 43/162 reads (27%) | catalogued as rs980801009, COSV99137052; called by muse, mutect2, varscan2
- CCNA1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765233671, COSV55220035; called by muse, mutect2, varscan2
- CCNC | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100412587; called by muse, mutect2, varscan2
- CCT8L2 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747115852, COSV100743275, COSV63462569; called by muse, mutect2, varscan2
- CD70 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs548095306, COSV55565708; called by muse, mutect2, varscan2
- CD72 | c.849C>A p.F283L | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99427407; called by muse, mutect2, varscan2
- CDC20 | c.959A>T p.D320V | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100196438; called by muse, mutect2, varscan2
- CDH16 | c.1586T>C p.V529A | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100233553, COSV100233842; called by muse, mutect2
- CDH16 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.403); catalogued as rs558954232, COSV100233686, COSV100233976; called by muse, mutect2, varscan2
- CDH9 | c.141G>T p.M47I | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV50279664, COSV99144018; called by muse, mutect2, varscan2
- CDK3 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs140567861, COSV56909913; called by muse, mutect2, varscan2
- CDK8 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101037164; called by muse, mutect2, varscan2
- CDON | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1012612060, COSV99701222; called by muse, mutect2, varscan2
- CEBPE | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs923787623, COSV52829648; called by muse, mutect2, varscan2
- CENPF | c.5477T>C p.I1826T | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV100871665; called by muse, mutect2, varscan2
- CENPK | c.65A>G p.E22G | Missense Mutation (SNP) | VAF 102/635 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV99669441; called by muse, mutect2, varscan2
- CEP41 | c.584A>G p.Y195C | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554417028, COSV99782692; called by muse, mutect2, varscan2
- CEP43 | c.1083_1085del p.E361del | In Frame Del (DEL) | VAF 18/79 reads (23%) | catalogued as rs754383350; called by pindel, varscan2
- CERS5 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as COSV100451977; called by muse, mutect2, varscan2
- CFAP70 | c.2506C>T p.Q836* | Nonsense Mutation (SNP) | VAF 97/408 reads (24%) | catalogued as COSV100160531; called by muse, mutect2, varscan2
- CFAP74 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs768950775, COSV54564219; called by muse, mutect2, varscan2
- CGA | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs145503313; called by muse, mutect2, varscan2
- CHD3 | c.3738G>T p.K1246N | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV100391151; called by muse, mutect2, varscan2
- CHD6 | c.198G>T p.E66D | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.253); catalogued as COSV58559537; called by muse, mutect2, varscan2
- CHIT1 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs557542364, COSV99705250; called by muse, mutect2, varscan2
- CHORDC1 | c.493-2A>T p.X165_splice | Splice Site (SNP) | VAF 48/162 reads (30%) | catalogued as COSV100272011; called by mutect2, varscan2
- CHRDL2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs766415152, COSV99733726; called by muse, mutect2, varscan2
- CHST1 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100346207; called by muse, mutect2, varscan2
- CIT | c.416T>G p.V139G | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV99949402; called by muse, mutect2, varscan2
- CKMT2 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV99562347; called by muse, mutect2, varscan2
- CLASP1 | c.2900G>T p.R967M | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99754506; called by muse, mutect2, varscan2
- CLTC | c.1864C>A p.L622I | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99292144; called by muse, mutect2, varscan2
- CNKSR1 | c.879G>A p.T293= (on ENST00000374253 / NM_001297647.2; = p.T286= on NM_006314.3) | Splice Region (SNP) | VAF 54/175 reads (31%) | catalogued as rs746626702, COSV64163261, COSV64163887; called by muse, mutect2, varscan2
- CNTN5 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV54303038, COSV99676123; called by muse, mutect2, varscan2
- CNTN5 | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 24/118 reads (20%) | catalogued as rs771353785, COSV99676130; called by muse, mutect2, varscan2
- CNTNAP2 | c.3047G>A p.R1016Q | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as rs143879959, COSV62265209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COBL | c.2152C>T p.R718* | Nonsense Mutation (SNP) | VAF 133/453 reads (29%) | catalogued as rs372919855; called by muse, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 32/84 reads (38%) | catalogued as rs374805044; called by mutect2, varscan2
- COL12A1 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs756803766, COSV59401555; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL21A1 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1040526013, COSV55152168; called by muse, mutect2, varscan2
- COL22A1 | c.2161G>A p.V721I | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100278154; called by muse, mutect2, varscan2
- COL25A1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs1030036795, COSV101211381; called by muse, mutect2, varscan2
- COL6A3 | c.5440G>T p.E1814* | Nonsense Mutation (SNP) | VAF 51/160 reads (32%) | catalogued as COSV55080065, COSV99797868; called by muse, mutect2, varscan2
- COL6A3 | c.3922C>T p.R1308W | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs140330124; called by muse, mutect2, varscan2
- COL6A3 | c.1574C>T p.T525M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs755178814, COSV55080308; ClinVar: benign; called by muse, mutect2, varscan2
- COLGALT1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs149722085; called by muse, mutect2, varscan2
- COP1 | c.1121C>T p.T374I | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.278); catalogued as COSV100443179; called by muse, mutect2, varscan2
- CPA1 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV99163259; called by muse, mutect2, varscan2
- CPEB2 | c.2962C>T p.Q988* | Nonsense Mutation (SNP) | VAF 89/336 reads (26%) | catalogued as COSV99470254; called by muse, mutect2, varscan2
- CREB3 | c.282_285del p.S94Rfs*10 | Frame Shift Del (DEL) | VAF 64/241 reads (27%) | catalogued as rs1369727531; called by mutect2, pindel, varscan2
- CSE1L | c.2528C>T p.A843V | Missense Mutation (SNP) | VAF 155/420 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as rs749686049, COSV99521996; called by muse, mutect2, varscan2
- CSNK1E | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 105/362 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63292132; called by mutect2, varscan2
- CSNK2A2 | c.230del p.K77Rfs*3 | Frame Shift Del (DEL) | VAF 61/217 reads (28%) | catalogued as COSV52643307; called by mutect2, pindel, varscan2
- CTCF | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.623); catalogued as COSV50490739; called by muse, mutect2, varscan2
- CTNNA1 | c.1055T>C p.M352T | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV100242608; called by muse, mutect2
- CXCR1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs772327936, COSV99826320; called by muse, mutect2, varscan2
- CYB5R2 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100207434; called by muse, mutect2, varscan2
- CYP2A6 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV56533848; called by muse, mutect2, varscan2
- CYP3A7 | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100312637; called by muse, mutect2, varscan2
- CYP4F3 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs113330239, COSV55413386; called by muse, mutect2, varscan2
- CYP7B1 | c.982T>C p.S328P | Missense Mutation (SNP) | VAF 87/340 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV100041570; called by muse, mutect2, varscan2
- DAAM2 | c.2900C>T p.A967V (on ENST00000274867 / NM_001201427.2; = p.A966V on NM_015345.3) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV99225511; called by muse, mutect2, varscan2
- DBH | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99708026; called by muse, mutect2, varscan2
- DBP | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99709321; called by muse, mutect2, varscan2
- DCAF4L2 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV60477323; called by muse, mutect2, varscan2
- DCHS1 | c.7357G>A p.E2453K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1279908624; called by muse, mutect2, varscan2
- DCPS | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs554435261, COSV99703433; called by muse, mutect2, varscan2
- DDI1 | c.773T>C p.F258S | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100158971; called by muse, mutect2, varscan2
- DDIAS | c.393G>A p.T131= | Splice Region (SNP) | VAF 33/147 reads (22%) | catalogued as rs762266588, COSV61273188; called by muse, mutect2, varscan2
- DDR1 | c.2618C>T p.P873L (on ENST00000324771; = p.P836L on NM_001954.4) | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779035359, COSV100241448; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 56/174 reads (32%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 112/465 reads (24%) | catalogued as rs772416332; called by mutect2, varscan2
- DENND2B | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1258045916, COSV58203528; called by muse, mutect2, varscan2
- DENND2C | c.1630G>C p.D544H (on ENST00000393274 / NM_001256404.2; = p.D487H on NM_198459.4) | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101283921; called by muse, mutect2, varscan2
- DGCR8 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100707920; called by muse, mutect2, varscan2
- DHTKD1 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 53/269 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs749788470, COSV99536341; called by muse, mutect2, varscan2
- DIPK2B | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs759687156, COSV65005170; called by muse, varscan2
- DIS3L2 | c.2059C>T p.R687W | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs372762400; ClinVar: uncertain significance; called by muse, varscan2
- DLG5 | c.5465C>T p.P1822L | Missense Mutation (SNP) | VAF 94/317 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.705); catalogued as rs931692281, COSV100967436; called by muse, mutect2, varscan2
- DMRTC2 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99523377; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 41/121 reads (34%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH11 | c.13240dup p.T4414Nfs*34 | Frame Shift Ins (INS) | VAF 29/118 reads (25%) | catalogued as rs759332741; called by mutect2, varscan2
- DNAH17 | c.5082G>T p.Q1694H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67761759; called by muse, mutect2, varscan2
- DNAH2 | c.5109G>T p.K1703N | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66722678; called by muse, mutect2, varscan2
- DNAH2 | c.7613G>A p.R2538Q | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772981855, COSV101209245, COSV101209286; called by muse, mutect2, varscan2
- DNAH2 | c.9929A>G p.D3310G | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101209248; called by muse, mutect2, varscan2
- DNAH3 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as COSV99767006; called by muse, mutect2, varscan2
- DNAH5 | c.11267G>T p.R3756M | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV99449037; called by muse, varscan2
- DNAH5 | c.9947del p.P3316Lfs*22 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | catalogued as rs1206989225; called by mutect2, pindel, varscan2
- DNAJC22 | c.224del p.P75Lfs*2 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs751047585; called by mutect2, varscan2
- DNMT1 | c.3866G>A p.R1289H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs564106859, COSV100532381; called by muse, mutect2, varscan2
- DOCK2 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.662); catalogued as COSV99911966; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 53/169 reads (31%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK9 | c.248C>T p.A83V (on ENST00000376460 / NM_001366676.2; = p.A84V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.205); catalogued as COSV100239040; called by muse, mutect2, varscan2
- DPP3 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377511860; called by muse, varscan2
- DPYD | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.156); catalogued as rs143815742, COSV64604165; called by muse, mutect2, varscan2
- DSCAML1 | c.739G>A p.V247I (on ENST00000321322; = p.V187I on NM_020693.4) | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as rs754760476, COSV100355757; called by muse, mutect2, varscan2
- DSPP | c.986C>A p.S329Y | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT tolerated, low confidence (0.9); PolyPhen possibly damaging (0.516); catalogued as rs376443462; called by muse, mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 58/180 reads (32%) | catalogued as rs772082432; called by mutect2, varscan2
- DYNC2H1 | c.5176C>T p.R1726* | Nonsense Mutation (SNP) | VAF 156/588 reads (27%) | catalogued as rs772321133, CM130524, COSV100518383; called by muse, varscan2
- DYNC2H1 | c.10114A>T p.T3372S | Missense Mutation (SNP) | VAF 105/347 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100518384; called by muse, mutect2, varscan2
- ECI2 | c.14A>G p.Y5C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs762001199, COSV60986157; called by muse, mutect2, varscan2
- ECM2 | c.30dup p.L11Sfs*8 | Frame Shift Ins (INS) | VAF 16/82 reads (20%) | catalogued as rs752987091; called by mutect2, varscan2
- EFS | c.740del p.G247Afs*140 | Frame Shift Del (DEL) | VAF 27/77 reads (35%) | catalogued as COSV53733035; called by mutect2, pindel, varscan2
- EHBP1 | c.2630G>A p.R877Q | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs201434475, COSV99860750; called by muse, mutect2, varscan2
- EIF2AK1 | c.367G>C p.A123P | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52241731, COSV99551837; called by muse, mutect2, varscan2
- EIF2B1 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 13/100 reads (13%) | catalogued as rs370678173; called by muse, mutect2, varscan2
- EIF2B2 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs372838502; called by muse, mutect2, varscan2
- EIF3F | c.941A>G p.Q314R | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.186); catalogued as rs765505343, COSV100562551; called by muse, mutect2, varscan2
- ELAVL2 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 101/330 reads (31%) | catalogued as COSV56365323; called by muse, mutect2, varscan2
- ELF1 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs766946264, COSV99523011; called by muse, mutect2, varscan2
- ELF1 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV99523013; called by muse, mutect2, varscan2
- ELK3 | c.14T>C p.I5T | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99957593; called by muse, mutect2, varscan2
- EME1 | c.1667A>G p.Q556R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99869533; called by muse, mutect2, varscan2
- EPG5 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); catalogued as COSV99957123, COSV99958212; called by muse, mutect2, varscan2
- EPHA3 | c.476A>G p.D159G | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.995); catalogued as COSV100344839; called by muse, mutect2, varscan2
- EPHA3 | c.2538del p.M847Wfs*10 | Frame Shift Del (DEL) | VAF 55/173 reads (32%) | catalogued as rs1317589623; called by mutect2, pindel, varscan2
- EPHA3 | c.2947G>A p.V983M | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs536144760, COSV60694629, COSV60712421; called by muse, mutect2, varscan2
- EPHA5 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV56647879; called by muse, mutect2, varscan2
- EPX | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs762203083, COSV99836468; called by muse, mutect2, varscan2
- ERBB4 | c.2867-1G>A p.X956_splice | Splice Site (SNP) | VAF 29/105 reads (28%) | catalogued as COSV100726439, COSV61493101; called by muse, mutect2, varscan2
- ERCC3 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV53425816; called by muse, mutect2, varscan2
- ERICH5 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1167461070, COSV100582758; called by muse, mutect2, varscan2
- ERICH6 | c.1151T>C p.V384A | Missense Mutation (SNP) | VAF 83/349 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV99901607; called by muse, mutect2, varscan2
- ERLEC1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 76/339 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs748288717, COSV99483013, COSV99483134; called by muse, mutect2, varscan2
- ETV4 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as rs754077603; called by muse, varscan2
- EVC | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs1286815295, COSV53832353; called by muse, mutect2, varscan2
- EXOC4 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1290075190, COSV99553590; called by muse, mutect2, varscan2
- F2 | c.1474T>G p.L492V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100319483; called by muse, mutect2
- FADD | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100096645; called by muse, mutect2, varscan2
- FAIM2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 102/200 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs751246525, COSV57738910; called by muse, mutect2, varscan2
- FAM120AOS | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV99465253; called by muse, mutect2, varscan2
- FAM120B | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.159); catalogued as COSV99379288; called by muse, mutect2, varscan2
- FAM221B | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); catalogued as rs943024291, COSV65074389; called by muse, mutect2, varscan2
- FAM78A | c.14del p.F5Sfs*36 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs758104834; called by mutect2, varscan2
- FANCD2 | c.3860G>T p.S1287I | Missense Mutation (SNP) | VAF 108/386 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99810345, COSV99811141; called by muse, varscan2
- FANCE | c.929dup p.V311Sfs*2 | Frame Shift Ins (INS) | VAF 26/96 reads (27%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, varscan2
- FANCM | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV99950980; called by muse, mutect2, varscan2
- FAT2 | c.5448T>A p.D1816E | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55812391; called by muse, mutect2, varscan2
- FAT2 | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs538842194, COSV55826643; called by muse, mutect2, varscan2
- FAT4 | c.8624G>A p.S2875N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs765905172, COSV100628413; called by muse, mutect2, varscan2
- FBLIM1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs763280418; called by muse, varscan2
- FBN2 | c.6412del p.D2138Tfs*111 | Frame Shift Del (DEL) | VAF 55/218 reads (25%) | catalogued as COSV52520596; called by mutect2, pindel, varscan2
- FBXO11 | c.2359G>A p.A787T (on ENST00000403359 / NM_001190274.2; = p.A703T on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99315823; called by muse, mutect2, varscan2
- FBXO11 | c.1295C>T p.A432V (on ENST00000403359 / NM_001190274.2; = p.A348V on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV57016534; called by muse, mutect2, varscan2
- FBXW10 | c.2854C>T p.R952C | Missense Mutation (SNP) | VAF 71/325 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1290401881, COSV100111396; called by muse, mutect2, varscan2
- FBXW7 | c.902T>C p.L301P (on ENST00000281708 / NM_001349798.2; = p.L221P on NM_018315.5) | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55932605; called by muse, mutect2
- FCHSD1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs768710494, COSV51836784; called by muse, mutect2, varscan2
- FCRL5 | c.380C>A p.A127E | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.449); catalogued as COSV100708750, COSV62519780; called by muse, mutect2, varscan2
- FGFBP1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs199528852, COSV52586067; called by muse, mutect2, varscan2
- FKBP15 | c.3307G>A p.E1103K | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs572313532, COSV53031810; called by muse, mutect2, varscan2
- FLCN | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1471793185, COSV53263731, COSV99550214; called by muse, mutect2, varscan2
- FLG | c.5912C>A p.A1971E | Missense Mutation (SNP) | VAF 145/409 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100911509; called by muse, mutect2, varscan2
- FLG | c.4549T>C p.Y1517H | Missense Mutation (SNP) | VAF 69/271 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100911510; called by muse, mutect2, varscan2
- FLG | c.3412A>G p.T1138A | Missense Mutation (SNP) | VAF 61/297 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs750063141, COSV100911511; called by muse, mutect2, varscan2
- FLII | c.3609G>T p.E1203D | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as COSV100375319; called by muse, mutect2
- FLRT2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs140606612; called by muse, mutect2, varscan2
- FNBP1L | c.1168C>A p.P390T (on ENST00000271234 / NM_001164473.2; = p.P332T on NM_017737.5) | Missense Mutation (SNP) | VAF 125/509 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99554346; called by muse, mutect2, varscan2
- FREM1 | c.2515del p.S839Lfs*8 | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | catalogued as COSV66527755; called by mutect2, pindel, varscan2
- FRMD3 | c.1303dup p.I435Nfs*10 | Frame Shift Ins (INS) | VAF 41/224 reads (18%) | catalogued as rs1353070115; called by mutect2, pindel, varscan2
- FSD2 | c.1646del p.G549Afs*4 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs1246402267; called by mutect2, pindel, varscan2
- FSD2 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100575115; called by muse, mutect2, varscan2
- GABPB1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV55014557; called by muse, varscan2
- GABRQ | c.1088G>T p.R363M | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100941217, COSV64782025; called by muse, mutect2, varscan2
- GALNT6 | c.1111A>G p.T371A | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.254); catalogued as COSV100695426; called by muse, mutect2, varscan2
- GAREM1 | c.1798C>T p.R600* (on ENST00000269209 / NM_001242409.2; = p.R599* on NM_022751.3) | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV52505678, COSV99331146; called by muse, mutect2, varscan2
- GAS7 | c.1163A>G p.D388G (on ENST00000432992 / NM_201433.2; = p.D248G on NM_003644.3) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100095348; called by muse, mutect2, varscan2
- GAS8 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV99243943; called by muse, mutect2
- GBE1 | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV101450075; called by muse, varscan2
- GBF1 | c.5114G>A p.R1705H (on ENST00000369983 / NM_001377137.1; = p.R1704H on NM_004193.3) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1482283229, COSV64144738; called by muse, mutect2, varscan2
- GCC1 | c.1310A>G p.E437G | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV100365510; called by muse, mutect2, varscan2
- GCNT3 | c.652G>C p.V218L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV101251810; called by muse, mutect2, varscan2
- GDAP2 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.837); catalogued as rs754920481, COSV65612689; called by muse, mutect2, varscan2
- GDPD3 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99531518; called by muse, mutect2, varscan2
- GMPPA | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100354621; called by muse, mutect2, varscan2
- GNB1 | c.946A>G p.S316G | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66100072; called by muse, mutect2
- GNPDA2 | c.282del p.F94Lfs*6 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | catalogued as rs1489322870; called by mutect2, varscan2
- GOLGA3 | c.4258G>A p.V1420M | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs142000244; called by muse, mutect2, varscan2
- GON4L | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 80/286 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99674133; called by muse, varscan2
- GPLD1 | c.2019C>T p.Y673= | Splice Region (SNP) | VAF 25/96 reads (26%) | catalogued as rs140430161; called by muse, mutect2, varscan2
- GPR143 | c.968C>A p.P323H | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV101102214; called by muse, mutect2, varscan2
- GPR151 | c.923T>C p.V308A | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99694736; called by muse, mutect2, varscan2
- GPRIN1 | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1193082156, COSV99991498; called by muse, mutect2, varscan2
- GPX5 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376708612; called by muse, mutect2, varscan2
- GPX6 | c.602A>C p.Q201P | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100724827; called by muse, mutect2, varscan2
- GRAMD1B | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772035485, COSV59200080; called by muse, mutect2, varscan2
- GRAMD4 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs755465455; called by muse, mutect2, varscan2
- GRIK4 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs753839952, COSV101483608; called by muse, mutect2, varscan2
- GRIN2A | c.1273del p.L425* | Frame Shift Del (DEL) | VAF 21/102 reads (21%) | catalogued as rs879253760; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- H3-5 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.777); catalogued as rs1215758766, COSV100461642; called by muse, mutect2, varscan2
- HAPLN3 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772799052, COSV62084253; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 29/98 reads (30%) | catalogued as rs746547303; called by mutect2, varscan2
- HCN4 | c.3531del p.P1179Lfs*2 | Frame Shift Del (DEL) | VAF 40/127 reads (31%) | catalogued as rs749503920, COSV56083147; called by mutect2, varscan2
- HDAC6 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs781914689, COSV100490770; called by muse, mutect2, varscan2
- HEATR5B | c.3731G>A p.R1244H | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs1450720418, COSV99249154; called by muse, mutect2, varscan2
- HECTD4 | c.10853A>G p.D3618G | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as COSV101107374; called by muse, mutect2, varscan2
- HEPACAM2 | c.935A>G p.D312G (on ENST00000394468 / NM_001039372.4; = p.D300G on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100506524; called by muse, mutect2, varscan2
- HEPHL1 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs183813405, COSV59890169; called by muse, mutect2, varscan2
- HEXIM2 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.335); catalogued as rs756765702, COSV100217906, COSV56236823; called by muse, mutect2
- HFE | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761203501, COSV100352578; called by muse, varscan2
- HIGD1B | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150260178; called by muse, mutect2, varscan2
- HIP1 | c.123T>C p.T41= | Splice Region (SNP) | VAF 33/122 reads (27%) | catalogued as COSV100417438; called by muse, mutect2, varscan2
- HIPK1 | c.2708T>C p.V903A | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV100478909; called by muse, mutect2, varscan2
- HIRIP3 | c.1237A>G p.K413E | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99662999; called by muse, mutect2, varscan2
- HMCN1 | c.16003G>A p.G5335S | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775664458, COSV99628397; called by muse, mutect2, varscan2
- HMG20A | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV100287742; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 110/338 reads (33%) | catalogued as rs761272507; called by mutect2, varscan2
- HRC | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.143); catalogued as rs1391905788, COSV99417874; called by muse, varscan2
- HSPA1L | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100989375; called by muse, mutect2, varscan2
- HSPG2 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs748189648; called by muse, varscan2
- IFT140 | c.1890A>C p.Q630H | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV101276374; called by muse, mutect2, varscan2
- IFT140 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs776789813, COSV68486659; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFT172 | c.4228G>A p.V1410M | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); catalogued as COSV53135936, COSV99562394; called by muse, mutect2, varscan2
- IGSF10 | c.2003G>A p.R668K | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs148479279; called by muse, mutect2, varscan2
- IGSF22 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as rs747280828, COSV100079660; called by muse, mutect2, varscan2
- IL1A | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV99641360; called by muse, mutect2, varscan2
- IL27RA | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs376141649, COSV54601751; called by muse, mutect2, varscan2
- INPP5F | c.919T>C p.Y307H | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100740106; called by muse, mutect2, varscan2
- INPPL1 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs200692358; called by muse, mutect2, varscan2
- IPCEF1 | c.243+2T>C p.X81_splice | Splice Site (SNP) | VAF 45/170 reads (26%) | catalogued as COSV99499599; called by muse, mutect2, varscan2
- IQSEC1 | c.2761G>A p.A921T | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs754408494, COSV56222453; called by muse, mutect2, varscan2
- IRS1 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs755583840, COSV100524433; called by muse, varscan2
- IRX2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100121697; called by muse, mutect2, varscan2
- ITGA3 | c.2554C>G p.L852V | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV99143565; called by muse, mutect2, varscan2
- ITPR1 | c.2088G>T p.E696D (on ENST00000354582; = p.E681D on NM_002222.7) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100230879; called by muse, mutect2, varscan2
- ITPR3 | c.7933G>A p.E2645K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753797425, COSV100951994; called by muse, mutect2, varscan2
- IVL | c.128del p.P43Hfs*22 | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | catalogued as COSV64216943; called by mutect2, pindel, varscan2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 42/148 reads (28%) | catalogued as rs774820321; called by mutect2, varscan2
- KBTBD7 | c.1032G>T p.E344D | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV101068094; called by muse, mutect2, varscan2
- KCNA10 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs776640538, COSV63904732; called by muse, mutect2, varscan2
- KCNH7 | c.968T>A p.L323H | Missense Mutation (SNP) | VAF 161/618 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100035587; called by muse, mutect2, varscan2
- KCNIP1 | c.194A>G p.Q65R (on ENST00000411494 / NM_001034837.3; = p.Q54R on NM_014592.4) | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1008260063, COSV100199179; called by muse, mutect2, varscan2
- KCNJ11 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs768909861, COSV60595626, COSV60595643; ClinVar: uncertain significance; called by muse, mutect2
- KCNK1 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs776795446, COSV100785688; called by muse, mutect2, varscan2
- KCNK13 | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as rs114305114, COSV99965644; called by muse, mutect2, varscan2
- KCNQ3 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.266); catalogued as COSV101196004; called by muse, mutect2, varscan2
- KCTD16 | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101568803; called by muse, mutect2, varscan2
- KHNYN | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750247971, COSV99249977; called by muse, varscan2
- KIAA1109 | c.11847A>G p.A3949= | Splice Region (SNP) | VAF 25/86 reads (29%) | catalogued as COSV99158746; called by muse, mutect2, varscan2
- KIAA1841 | c.214T>C p.S72P | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99693614; called by muse, mutect2, varscan2
- KIAA2026 | c.4549A>G p.T1517A | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs747635824, COSV101198994; called by muse, varscan2
- KIF18B | c.2359G>A p.V787I (on ENST00000593135 / NM_001265577.2; = p.V799I on NM_001264573.2) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs745510143, COSV59274132; called by muse, mutect2, varscan2
- KIF21A | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 114/290 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100735424; called by muse, varscan2
- KIF21A | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 158/686 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143166999; called by muse, mutect2, varscan2
- KIF21B | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs770974908, COSV59752730; called by muse, mutect2, varscan2
- KIRREL3 | c.1052A>G p.D351G | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101585703; called by muse, mutect2, varscan2
- KLC4 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99431838; called by muse, mutect2, varscan2
- KLF1 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs760145920; called by muse, varscan2
- KLF8 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63848092; called by muse, mutect2, varscan2
- KLHL36 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.224); catalogued as rs763314913; called by muse, varscan2
- KLHL41 | c.215del p.K72Rfs*3 | Frame Shift Del (DEL) | VAF 66/166 reads (40%) | catalogued as COSV52930337; called by mutect2, varscan2
- KLRC3 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 185/418 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); catalogued as rs569300623, COSV101122906, COSV67250668; called by muse, mutect2, varscan2
- KMT2C | c.7387C>T p.R2463C | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs750213944, COSV100071198; called by muse, mutect2, varscan2
- KMT2D | c.2702C>A p.S901Y | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as rs1465221310; called by muse, mutect2
- KRI1 | c.1359C>T p.N453= | Splice Region (SNP) | VAF 22/71 reads (31%) | catalogued as rs780845086, COSV100470064; called by muse, mutect2, varscan2
- KRT3 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.033); catalogued as rs1315514569, COSV100527026; called by muse, mutect2, varscan2
- KRT6C | c.1663T>A p.S555T | Missense Mutation (SNP) | VAF 119/256 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99359944; called by muse, mutect2, varscan2
- KRT82 | c.1255A>G p.T419A | Missense Mutation (SNP) | VAF 87/183 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99233535; called by muse, mutect2, varscan2
- KRTAP10-6 | c.1034G>A p.C345Y | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV100553247; called by muse, mutect2, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 43/193 reads (22%) | catalogued as rs770565486; called by mutect2, pindel, varscan2
- LAIR1 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57308730; called by muse, mutect2, varscan2
- LAMA1 | c.1487del p.N496Tfs*27 | Frame Shift Del (DEL) | VAF 21/125 reads (17%) | catalogued as rs1406609727; called by mutect2, pindel, varscan2
- LAMC3 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs376297941; called by muse, varscan2
- LANCL2 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs776099480, COSV54649306, COSV54651496; called by muse, mutect2, varscan2
- LARGE1 | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100505200; called by muse, mutect2, varscan2
- LARP4B | c.2113G>T p.A705S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV100295294; called by muse, mutect2, varscan2
- LGI4 | c.1354G>A p.G452S | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755198882, COSV59533557, COSV59533573; called by muse, mutect2, varscan2
- LHFPL2 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66716370; called by muse, mutect2, varscan2
- LIPE | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as rs1434397516, COSV99734068; called by muse, mutect2, varscan2
- LPXN | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1176798296; called by muse, mutect2, varscan2
- LRCH4 | c.176G>C p.R59P | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99575276; called by muse, varscan2
- LRFN2 | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as rs371754423, COSV100599505; called by muse, mutect2, varscan2
- LRIG2 | c.3130A>G p.R1044G | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); catalogued as COSV100743284; called by muse, mutect2, varscan2
- LRP1 | c.9433C>T p.R3145C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99675609, COSV99677603; called by muse, mutect2, varscan2
- LRP1B | c.3377C>T p.S1126L | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101256072; called by muse, mutect2, varscan2
- LRP2 | c.2917G>A p.A973T | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.151); catalogued as rs752290503, COSV55575991, COSV99787419; called by muse, varscan2
- LRP2 | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99788109; called by muse, mutect2, varscan2
- LRRC52 | c.212T>C p.M71T | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99673825; called by muse, mutect2, varscan2
- LUM | c.784T>C p.S262P | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99899007; called by muse, mutect2, varscan2
- LY6K | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs782212141, COSV52832959; called by muse, mutect2, varscan2
- MAB21L2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100462110; called by muse, mutect2, varscan2
- MACC1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs202049959; called by muse, mutect2, varscan2
- MACO1 | c.849A>G p.I283M | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.078); catalogued as COSV100975141; called by muse, mutect2, varscan2
- MAN1A1 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs766457235, COSV100870632; called by muse, mutect2, varscan2
- MAN2C1 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs753887151; called by muse, varscan2
- MAP2K4 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV100796222; called by muse, mutect2, varscan2
- MAP3K21 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100786260; called by muse, varscan2
- MAP4K4 | c.2870A>C p.K957T (on ENST00000347699 / NM_001242559.2; = p.K875T on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/321 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100154616; called by muse, mutect2, varscan2
- MAPK10 | c.343T>G p.L115V (on ENST00000359221 / NM_001351625.2; = p.L153V on NM_002753.5) | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100174288; called by muse, mutect2, varscan2
- MAPKAPK5 | c.23A>G p.D8G | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as rs773408629, COSV101459644; called by muse, mutect2, varscan2
- MATN2 | c.724T>C p.C242R | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99646196; called by muse, mutect2, varscan2
- MBTPS1 | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs768994789, COSV58570153; called by muse, mutect2, varscan2
- MCM4 | c.2266A>G p.I756V | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1382021959, COSV100031479; called by muse, mutect2, varscan2
- MDH1 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 30/121 reads (25%) | catalogued as rs1183532328, COSV99250985; called by muse, mutect2, varscan2
- MDN1 | c.10147C>T p.R3383W | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.791); catalogued as rs770965969, COSV101021232; called by muse, mutect2, varscan2
- MED1 | c.437del p.N146Ifs*24 | Frame Shift Del (DEL) | VAF 90/357 reads (25%) | catalogued as COSV56125174; called by mutect2, pindel, varscan2
- MEF2C | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60927625; called by muse, mutect2, varscan2
- MEGF8 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as rs922693299, COSV52078406; called by muse, mutect2, varscan2
- MEGF8 | c.4108C>T p.R1370* (on ENST00000251268 / NM_001271938.2; = p.R1303* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as rs1195649417, COSV99235903; called by muse, mutect2, varscan2
- MEPCE | c.1184A>G p.H395R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs760815358, COSV52769178; called by muse, mutect2, varscan2
- METTL22 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 37/154 reads (24%) | catalogued as COSV99371674; called by muse, mutect2, varscan2
- MFAP4 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1160355423, COSV100218880; called by muse, mutect2, varscan2
- MFHAS1 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV52284172; called by muse, mutect2, varscan2
- MFSD2B | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs751215494, COSV57853996; called by muse, mutect2, varscan2
- MGA | c.462dup p.R155Efs*24 | Frame Shift Ins (INS) | VAF 76/289 reads (26%) | catalogued as COSV99580018; called by mutect2, pindel, varscan2
- MICAL2 | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); catalogued as COSV99817318; called by muse, mutect2, varscan2
- MKI67 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV100896464, COSV64073805; called by muse, mutect2, varscan2
- MLNR | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as rs200347707; called by muse, varscan2
- MMP21 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as rs762663007, COSV64288627; called by muse, mutect2, varscan2
- MON2 | c.5061_5063del p.S1688del | In Frame Del (DEL) | VAF 58/313 reads (19%) | catalogued as rs1565723532; called by pindel, varscan2
- MPP3 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771313380; called by muse, varscan2
- MPP4 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs753283774, COSV59628695; called by muse, mutect2, varscan2
- MS4A1 | c.708del p.E237Nfs*6 | Frame Shift Del (DEL) | VAF 69/320 reads (22%) | catalogued as rs779922206; called by mutect2, varscan2
- MST1R | c.4120C>T p.R1374C | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs772336656, COSV99618550; called by muse, varscan2
- MTHFR | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs760349899, COSV57171655; called by muse, mutect2, varscan2
- MTMR10 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs769982335, COSV58727770; called by muse, mutect2, varscan2
- MTUS2 | c.2237G>A p.C746Y | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1472387074, COSV101462179; called by muse, mutect2, varscan2
- MUC16 | c.36080G>A p.R12027Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); catalogued as rs769222839, COSV67471709; called by muse, mutect2, varscan2
- MUC16 | c.19801A>G p.T6601A | Missense Mutation (SNP) | VAF 27/443 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as COSV101199657; called by muse, mutect2
- MX1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1374806050, COSV55818896, COSV99912605; called by muse, mutect2, varscan2
- MYBL1 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV101576528; called by muse, mutect2, varscan2
- MYBPC1 | c.684G>C p.Q228H (on ENST00000550270 / NM_206820.2; = p.Q253H on NM_002465.4) | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV100637950; called by muse, mutect2, varscan2
- MYCT1 | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs755298602, COSV100924066; called by muse, mutect2, varscan2
- MYEF2 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99981530; called by muse, mutect2, varscan2
- MYH11 | c.4414G>A p.D1472N | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763594267, COSV100258751; called by muse, mutect2, varscan2
- MYH14 | c.1830G>A p.W610* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as COSV99222552; called by muse, mutect2, varscan2
- MYH7 | c.5065C>T p.R1689C | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730880915, COSV62522904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.2090G>T p.R697M | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV101238390; called by muse, mutect2, varscan2
- MYO16 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1260492120, COSV51781943; called by muse, mutect2, varscan2
- MYO18B | c.5618G>A p.R1873Q | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs765439956, COSV59133694; called by muse, varscan2
- MYO3B | c.500_502del p.E167del | In Frame Del (DEL) | VAF 21/85 reads (25%) | catalogued as rs1559305504; called by mutect2, pindel, varscan2
- MYT1L | c.2872G>A p.D958N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs762411264; called by muse, varscan2
- NAA11 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs781256858, COSV99727331; called by muse, mutect2, varscan2
- NAA15 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 89/337 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV99649501; called by muse, mutect2, varscan2
- NADK | c.180-2A>G p.X60_splice | Splice Site (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100410837; called by muse, mutect2, varscan2
- NALCN | c.2939C>T p.S980L | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs748664264, COSV51920725; called by muse, mutect2, varscan2
- NAP1L3 | c.964G>T p.V322F | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100220328, COSV59076623; called by muse, mutect2, varscan2
- NCAPG | c.2417C>A p.T806K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99265908; called by muse, mutect2, varscan2
- NCKAP1L | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV53205016; called by muse, mutect2, varscan2
- NCL | c.615C>A p.D205E | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100502333; called by muse, mutect2, varscan2
- NCOR1 | c.7244A>G p.Q2415R | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.142); catalogued as rs1047907822, COSV99249536; called by muse, mutect2, varscan2
- NDUFB2 | c.130T>C p.Y44H | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV99199970; called by muse, mutect2, varscan2
- NDUFS1 | c.155C>A p.A52D | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99260836, COSV99261290; called by muse, varscan2
- NEB | c.14840C>T p.S4947L | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs780754459, COSV51269633; called by mutect2, varscan2
- NENF | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 73/291 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100877085, COSV65341481; called by muse, mutect2, varscan2
- NES | c.3473C>A p.P1158H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV100957852; called by muse, mutect2, varscan2
- NFXL1 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs1451919026, COSV100216769; called by muse, mutect2, varscan2
- NFYC | c.641A>G p.Q214R | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as COSV58128536; called by muse, mutect2, varscan2
- NID1 | c.2558G>A p.R853Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); catalogued as rs1168383337, COSV51616605; called by muse, mutect2, varscan2
- NIM1K | c.775del p.V259Cfs*7 | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | catalogued as rs769979471, COSV58143570; called by mutect2, pindel, varscan2
- NLRP1 | c.1748del p.K583Rfs*14 | Frame Shift Del (DEL) | VAF 46/195 reads (24%) | catalogued as COSV52567752; called by mutect2, pindel, varscan2
- NLRP5 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs770891485, COSV66764352; called by muse, mutect2, varscan2
- NLRP7 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs139884333; called by muse, mutect2, varscan2
- NOMO1 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 329/1259 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs142296824; called by muse, mutect2, varscan2
- NOTCH2 | c.5996del p.N1999Mfs*32 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs1446995271; called by pindel, varscan2
- NPAS4 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1429692302, COSV60652048; called by muse, mutect2
- NPHS1 | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV62288981; called by muse, mutect2, varscan2
- NPSR1 | c.238_240del p.K80del | In Frame Del (DEL) | VAF 59/302 reads (20%) | catalogued as rs752444500; called by pindel, varscan2
- NR2C1 | c.1366A>G p.N456D | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100280435; called by muse, mutect2, varscan2
- NR4A2 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV59892955; called by muse, mutect2, varscan2
- NRXN1 | c.3016G>C p.D1006H | Missense Mutation (SNP) | VAF 128/501 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100454756, COSV58444999; called by muse, mutect2, varscan2
- NRXN1 | c.1841A>G p.Y614C | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100454760; called by muse, varscan2
- NTN1 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); catalogued as rs1160517048, COSV99432835; called by muse, mutect2
- NTSR2 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs369667788; called by muse, mutect2, varscan2
- NUB1 | c.990del p.K330Nfs*2 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | catalogued as rs760102115; called by mutect2, varscan2
- NUP107 | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV57494342; called by muse, mutect2, varscan2
- NUP98 | c.3983del p.N1328Tfs*89 (on ENST00000359171 / NM_001365126.1; = p.N1311Tfs*89 on NM_016320.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 68/259 reads (26%) | catalogued as rs1214420150; called by mutect2, pindel, varscan2
- OBSL1 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs369090547, COSV54731459; called by muse, mutect2, varscan2
- OGT | c.487C>A p.L163M | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101035354; called by muse, varscan2
- OMA1 | c.1462T>C p.S488P | Missense Mutation (SNP) | VAF 70/288 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV100678071; called by muse, mutect2, varscan2
- OR10H4 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100437712; called by muse, mutect2, varscan2
- OR12D2 | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV101011253, COSV65828062; called by muse, mutect2, varscan2
- OR2B3 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101013785; called by muse, mutect2, varscan2
- OR2F1 | c.918G>T p.W306C | Missense Mutation (SNP) | VAF 102/244 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV101231306, COSV67331678; called by muse, mutect2, varscan2
- OR5D13 | c.130A>G p.N44D | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100686846; called by muse, mutect2, varscan2
- OR5R1 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV100393413; called by muse, mutect2, varscan2
- OR8D2 | c.934T>C p.*312Rext*? | Nonstop Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as COSV100658977; called by muse, mutect2, varscan2
- ORC1 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100856655; called by muse, mutect2, varscan2
- OSBPL6 | c.483G>C p.L161F | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99507298, COSV99507430; called by muse, mutect2, varscan2
- OTUD4 | c.1370G>A p.R457H (on ENST00000447906 / NM_001366057.1; = p.R392H on NM_001102653.1) | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs759518520, COSV101485967; called by muse, varscan2
- PACSIN3 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs753557964, COSV100096316; called by muse, varscan2
- PAFAH1B1 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101250379; called by muse, mutect2, varscan2
- PAN3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs765586023, COSV56701201; called by muse, mutect2, varscan2
- PATE2 | c.53-2A>G p.X18_splice | Splice Site (SNP) | VAF 70/313 reads (22%) | catalogued as COSV100653447; called by muse, mutect2, varscan2
- PATJ | c.1363T>C p.S455P | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.174); catalogued as rs771284772, COSV100334037; called by muse, varscan2
- PCDH1 | c.1376A>C p.Q459P | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99746043; called by muse, mutect2, varscan2
- PCDH19 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV55265789; called by muse, mutect2, varscan2
- PCDHA12 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.913); catalogued as COSV56532425; called by muse, mutect2, varscan2
- PCDHA4 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as COSV100793379, COSV63543942; called by muse, varscan2
- PCDHA8 | c.1874G>C p.G625A | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.168); catalogued as COSV65327415; called by muse, mutect2, varscan2
- PCDHAC2 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53848370; called by muse, mutect2, varscan2
- PCDHGA5 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as COSV54014928; called by muse, mutect2, varscan2
- PCDHGC3 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.417); catalogued as COSV52751363; called by muse, mutect2, varscan2
- PCF11 | c.3185G>T p.R1062I | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV53527059; called by muse, mutect2, varscan2
- PCLO | c.13585G>A p.E4529K | Missense Mutation (SNP) | VAF 75/256 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV100431655, COSV61626344; called by muse, mutect2, varscan2
- PCOLCE2 | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV99930609; called by muse, mutect2, varscan2
- PDGFRB | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs368602685; called by muse, varscan2
- PDHB | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100240139; called by muse, mutect2, varscan2
- PDLIM5 | c.989T>C p.L330P | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100523606; called by muse, mutect2, varscan2
- PDS5A | c.3076G>A p.D1026N | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.967); catalogued as COSV100337325; called by muse, mutect2, varscan2
- PDZRN3 | c.2860C>T p.R954C | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1280414613, COSV55189976, COSV55196553, COSV55212179; called by muse, mutect2, varscan2
- PDZRN3 | c.778G>T p.G260* | Nonsense Mutation (SNP) | VAF 46/146 reads (32%) | catalogued as COSV55208092; called by muse, mutect2, varscan2
- PGBD4 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.349); catalogued as COSV56626642; called by muse, mutect2, varscan2
- PHF6 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV100136443, COSV59704164; called by muse, mutect2, varscan2
- PHF7 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV99963872; called by muse, mutect2, varscan2
- PHTF1 | c.601del p.W201Gfs*12 | Frame Shift Del (DEL) | VAF 64/251 reads (25%) | catalogued as rs1156707888; called by pindel, varscan2
- PIKFYVE | c.5396C>T p.T1799I | Missense Mutation (SNP) | VAF 135/402 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs147015179; called by muse, mutect2, varscan2
- PIPOX | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV100037971; called by muse, mutect2, varscan2
- PITX2 | c.827C>T p.T276M (on ENST00000354925 / NM_001204397.1; = p.T283M on NM_000325.6) | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100146295; called by muse, mutect2, varscan2
- PIWIL2 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs368245312; called by muse, mutect2, varscan2
- PKHD1 | c.5551G>A p.D1851N | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs867595938, COSV100582837; called by muse, mutect2, varscan2
- PKHD1L1 | c.7271T>A p.L2424H | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV101006026; called by muse, mutect2, varscan2
- PLA2R1 | c.4304G>A p.R1435Q | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs182334014; called by muse, mutect2, varscan2
- PLCD4 | c.1029C>A p.S343R | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs550691262, COSV101346875; called by muse, mutect2, varscan2
- PLEKHA5 | c.2995del p.T999Lfs*17 | Frame Shift Del (DEL) | VAF 65/158 reads (41%) | catalogued as rs759995048, COSV54701412; called by mutect2, varscan2
- PLXDC1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748638753, COSV100195264; called by muse, mutect2, varscan2
- PNP | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs1466345881, COSV100828956; called by muse, mutect2, varscan2
- PNPLA5 | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1284767858, COSV53375057, COSV53375959; called by muse, mutect2, varscan2
- PODXL2 | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1291697947; called by muse, mutect2, varscan2
- POGZ | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 80/281 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99652679; called by muse, mutect2, varscan2
- POLH | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as rs201365711, COSV100947758; called by muse, mutect2, varscan2
- POM121L12 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV68693158; called by muse, mutect2
- POU2F3 | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); catalogued as COSV99501035; called by muse, mutect2, varscan2
- PPIC | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217806551, COSV60575464; called by muse, mutect2, varscan2
- PPM1H | c.678dup p.T227Hfs*12 | Frame Shift Ins (INS) | VAF 17/49 reads (35%) | catalogued as rs776895562; called by mutect2, pindel, varscan2
- PPP1R12A | c.2749A>G p.R917G | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs61756420, COSV99700296; called by muse, mutect2, varscan2
- PPP1R32 | c.1254C>A p.S418R | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV100087796, COSV58545891; called by muse, mutect2, varscan2
- PPP1R3A | c.1428del p.N476Kfs*4 | Frame Shift Del (DEL) | VAF 97/390 reads (25%) | catalogued as rs1056475720, COSV52881818; called by mutect2, pindel, varscan2
- PRAG1 | c.2047C>T p.Q683* | Nonsense Mutation (SNP) | VAF 111/326 reads (34%) | catalogued as rs1197723743, COSV100422139; called by muse, mutect2, varscan2
- PRDM2 | c.5038T>C p.Y1680H | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV99341517; called by muse, mutect2, varscan2
- PRDM9 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs764241201, COSV57010337, COSV57015844; called by muse, varscan2
- PREX1 | c.3062G>A p.C1021Y | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV64249751; called by muse, mutect2, varscan2
- PRKCG | c.689A>G p.N230S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99668926; called by muse, mutect2, varscan2
- PRKD1 | c.761G>C p.G254A | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV100120127; called by muse, mutect2, varscan2
- PRPF4 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV65252823; called by muse, mutect2, varscan2
- PRSS22 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50720859, COSV99361830; called by muse, mutect2, varscan2
- PRUNE2 | c.4439G>A p.G1480E | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749706692, COSV100944500; called by muse, mutect2, varscan2
- PSEN2 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100423038; called by muse, mutect2, varscan2
- PTGFR | c.585C>A p.D195E | Missense Mutation (SNP) | VAF 91/327 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.103); catalogued as rs1345314797, COSV100882281; called by muse, mutect2, varscan2
- PTPN5 | c.1510G>A p.G504S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168728753, COSV60030497; called by muse, varscan2
- PTPRB | c.550A>G p.T184A | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.314); catalogued as COSV99717183, COSV99719399; called by muse, mutect2, varscan2
- PTPRC | c.1883T>C p.M628T | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV100722567; called by muse, mutect2, varscan2
- PTPRG | c.3088G>T p.G1030* | Nonsense Mutation (SNP) | VAF 28/132 reads (21%) | catalogued as COSV99874596; called by muse, mutect2, varscan2
- PTPRK | c.2741A>C p.N914T (on ENST00000368215 / NM_001291984.2; = p.N915T on NM_002844.4) | Missense Mutation (SNP) | VAF 131/422 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV63893094; called by muse, mutect2, varscan2
- PTPRR | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 159/394 reads (40%) | catalogued as COSV51729025; called by muse, mutect2, varscan2
- PTPRT | c.4140T>G p.N1380K | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV100626882; called by muse, mutect2, varscan2
- PTPRT | c.2866C>T p.H956Y | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV61986989; called by muse, mutect2, varscan2
- PZP | c.1031C>A p.S344Y | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV99737573; called by muse, mutect2, varscan2
- RAG2 | c.1496del p.K499Sfs*4 | Frame Shift Del (DEL) | VAF 135/530 reads (25%) | catalogued as rs1251406873; called by mutect2, pindel, varscan2
- RALGAPA1 | c.4067A>C p.D1356A | Missense Mutation (SNP) | VAF 76/270 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV99354443; called by muse, varscan2
- RALGAPB | c.2609G>T p.G870V | Missense Mutation (SNP) | VAF 119/271 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99485135; called by muse, mutect2, varscan2
- RASL10B | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs1299841656; called by muse, mutect2, varscan2
- RAVER1 | c.1071del p.K358Sfs*177 (on ENST00000615032; = p.K358Sfs*149 on NM_133452.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/105 reads (29%) | catalogued as rs773370779, COSV99532335; called by mutect2, varscan2
- RBAK-RBAKDN | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs773470222, COSV101208252; called by muse, mutect2, varscan2
- RBM6 | c.2280del p.K760Nfs*101 | Frame Shift Del (DEL) | VAF 36/144 reads (25%) | catalogued as rs1559645154; called by mutect2, varscan2
- RCVRN | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs139258757; called by muse, mutect2, varscan2
- RECQL | c.1191T>A p.N397K | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101388968; called by muse, mutect2, varscan2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 122/342 reads (36%) | catalogued as rs753959887; called by mutect2, varscan2
- RFLNB | c.243G>T p.E81D | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100225050; called by muse, mutect2, varscan2
- RFX3 | c.2013T>A p.D671E | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.551); catalogued as COSV101137811; called by muse, mutect2, varscan2
- RGS3 | c.2588G>T p.S863I (on ENST00000350696 / NM_001282923.2; = p.S582I on NM_130795.4) | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs1388533089, COSV100636703; called by muse, mutect2, varscan2
- RGS9 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs866147892, COSV52225793, COSV52227907; called by muse, mutect2, varscan2
- RHOA | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV69042372, COSV69043849; called by muse, mutect2, varscan2
- RIMKLB | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.045); catalogued as COSV100223866; called by muse, mutect2, varscan2
- RIOK2 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1161416386, COSV51611853; called by muse, mutect2, varscan2
- RIPK4 | c.1550G>A p.R517H (on ENST00000352483; = p.R469H on NM_020639.3) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.586); catalogued as rs1288169822, COSV60190880; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 40/143 reads (28%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF43 | c.1322del p.P441Lfs*61 | Frame Shift Del (DEL) | VAF 23/83 reads (28%) | catalogued as rs755967475, COSV68457961; called by mutect2, pindel, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 46/135 reads (34%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- ROBO1 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs752516128, COSV101458656; called by muse, mutect2, varscan2
- RPL35 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as rs541571516, COSV100780831; called by muse, mutect2, varscan2
- RSF1 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs748850046, COSV100407151; called by muse, mutect2, varscan2
- RUNX2 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 70/250 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs1203066173, COSV100767328; called by muse, mutect2, varscan2
- RYR1 | c.8894G>A p.R2965H | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.288); catalogued as COSV62098450; called by muse, mutect2, varscan2
- SCLT1 | c.1328A>G p.Y443C | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs750715703, COSV99827980; called by muse, mutect2, varscan2
- SCN7A | c.2409T>A p.D803E | Missense Mutation (SNP) | VAF 106/371 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV69272230; called by muse, mutect2, varscan2
- SCN7A | c.233del p.N78Ifs*4 | Frame Shift Del (DEL) | VAF 76/213 reads (36%) | catalogued as rs764500272; called by mutect2, varscan2
- SDK1 | c.2273C>A p.T758K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67392225; called by muse, mutect2, varscan2
- SEC14L4 | c.824G>T p.R275M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV99742918; called by muse, mutect2, varscan2
- SEMA4D | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1398942351, COSV59396572; called by muse, mutect2, varscan2
- SEMA6D | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs765456604, COSV60379446; called by muse, mutect2, varscan2
- SERPINI2 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303012392, COSV52987865; called by muse, varscan2
- SFPQ | c.1462T>C p.Y488H | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.837); catalogued as COSV100599407; called by muse, mutect2, varscan2
- SFRP4 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs769250207; called by muse, varscan2
- SH3BP5L | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100822000; called by muse, mutect2, varscan2
- SHANK1 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1188839671, COSV53246173; called by muse, varscan2
- SHD | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV73378706; called by muse, mutect2, varscan2
- SHOC1 | c.931A>G p.M311V | Missense Mutation (SNP) | VAF 101/294 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100597555; called by muse, mutect2, varscan2
- SHROOM3 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.478); catalogued as COSV56022443; called by muse, mutect2, varscan2
- SI | c.887del p.L296* | Frame Shift Del (DEL) | VAF 53/244 reads (22%) | catalogued as rs769103567, COSV52291108; called by mutect2, pindel, varscan2
- SIM1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1217153562, COSV99492304; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC16A13 | c.1184_1186del p.F395del | In Frame Del (DEL) | VAF 29/105 reads (28%) | catalogued as rs752626452; called by pindel, varscan2
- SLC25A31 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs868692313, COSV55422424; called by muse, mutect2, varscan2
- SLC30A8 | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV69969419, COSV69969771; called by muse, mutect2, varscan2
- SLC37A2 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs543083936, COSV53522023; called by muse, mutect2, varscan2
- SLC39A7 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.054); catalogued as COSV100807683; called by muse, mutect2, varscan2
- SLC6A3 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs138948519; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC7A2 | c.1553C>T p.A518V (on ENST00000494857 / NM_001370338.1; = p.A557V on NM_003046.6) | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.059); catalogued as COSV99134729; called by muse, mutect2, varscan2
- SLC7A4 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs377663916; called by muse, varscan2
- SLC9C2 | c.1837G>T p.G613* | Nonsense Mutation (SNP) | VAF 52/230 reads (23%) | catalogued as COSV62945484; called by muse, mutect2, varscan2
- SLCO6A1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.288); catalogued as rs201223529; called by muse, mutect2, varscan2
- SLFN12 | c.555dup p.D186* | Frame Shift Ins (INS) | VAF 34/116 reads (29%) | catalogued as rs747319777; called by mutect2, varscan2
- SMAD9 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV63204678; called by muse, mutect2, varscan2
- SMC4 | c.1858G>T p.G620W | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100644020; called by muse, mutect2, varscan2
- SMG7 | c.2545del p.M849* | Frame Shift Del (DEL) | VAF 32/80 reads (40%) | catalogued as rs749889899; called by mutect2, varscan2
- SMPX | c.18G>C p.Q6H | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101069785, COSV65277733; called by muse, mutect2
- SNAI1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54863674; called by muse, mutect2
- SNAPC5 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs144538572, COSV57206339; called by muse, varscan2
- SNW1 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV55052787; called by muse, mutect2, varscan2
- SNX25 | c.1716dup p.V573Sfs*7 | Frame Shift Ins (INS) | VAF 118/400 reads (30%) | catalogued as rs780499770; called by mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 24/83 reads (29%) | catalogued as rs768873484; called by mutect2, varscan2
- SORBS2 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 70/249 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53010149; called by muse, mutect2, varscan2
- SP4 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.292); catalogued as rs1305715394, COSV56021999; called by muse, varscan2
- SPATA16 | c.44G>T p.R15M | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV63531169; called by muse, mutect2, varscan2
- SPATA31D1 | c.733T>C p.F245L | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.318); catalogued as COSV100782741; called by muse, mutect2
- SPHKAP | c.4112C>T p.P1371L | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.321); catalogued as rs772667973, COSV100764080; called by muse, mutect2, varscan2
- SPOCK2 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770205958, COSV58036777; called by muse, mutect2, varscan2
- SPRYD7 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as rs772902529, COSV62523690; called by muse, mutect2, varscan2
- SPTB | c.2518C>T p.R840C | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759218961, COSV101072094, COSV67633990; called by muse, mutect2, varscan2
- SRCAP | c.600G>T p.K200N | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99350000; called by muse, mutect2, varscan2
- SRCIN1 | c.460C>T p.R154C (on ENST00000621492; = p.R120C on NM_025248.3) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1156937402; called by muse, mutect2, varscan2
- SRP72 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.57); catalogued as rs763555511, COSV100714300; called by muse, mutect2, varscan2
- SRPX | c.930G>A p.W310* | Nonsense Mutation (SNP) | VAF 59/121 reads (49%) | catalogued as COSV100656034; called by muse, mutect2, varscan2
- SRRM1 | c.398A>G p.Q133R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV100104533; called by muse, mutect2, varscan2
- ST8SIA3 | c.792del p.F264Lfs*8 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as COSV60655405; called by mutect2, pindel, varscan2
- STAB2 | c.4328G>A p.S1443N | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV101185909; called by muse, mutect2, varscan2
- STAMBPL1 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV100905325; called by muse, mutect2, varscan2
- STAT5B | c.1776-2A>G p.X592_splice | Splice Site (SNP) | VAF 26/99 reads (26%) | catalogued as COSV99510921; called by muse, mutect2, varscan2
- STXBP5L | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV99873749; called by muse, mutect2, varscan2
- SUCLA2 | c.1282C>T p.R428W (on ENST00000643023; = p.R407W on NM_003850.3) | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233249991, CM162763, COSV66222631; called by muse, mutect2, varscan2
- SULT1B1 | c.575del p.L192Cfs*6 | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | catalogued as rs1316574540; called by mutect2, pindel, varscan2
- SYMPK | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as COSV55611282; called by muse, mutect2, varscan2
- SYNE1 | c.25241C>T p.T8414M (on ENST00000367255 / NM_182961.4; = p.T8366M on NM_033071.3) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs759512753, COSV54946518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT5 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 142/478 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62831122; called by muse, mutect2, varscan2
- TAS2R38 | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV101516415; called by muse, mutect2, varscan2
- TASOR | c.1834T>C p.Y612H (on ENST00000355628 / NM_001365636.2; = p.Y216H on NM_015224.3) | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100843511; called by muse, mutect2, varscan2
- TBC1D23 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.292); catalogued as COSV61368494; called by muse, mutect2, varscan2
- TBC1D28 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs372865587, COSV100561038; called by muse, mutect2, varscan2
- TCHH | c.3172C>T p.Q1058* | Nonsense Mutation (SNP) | VAF 43/174 reads (25%) | catalogued as COSV100915010; called by muse, mutect2, varscan2
- TECTA | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1032030939, CM1310314, COSV50713199; called by muse, mutect2
- TEK | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 45/246 reads (18%) | catalogued as COSV101193377; called by muse, mutect2, varscan2
- TENM1 | c.3665C>T p.S1222L | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs747368597, COSV64424199; called by muse, mutect2, varscan2
- TENM2 | c.5218C>T p.R1740C (on ENST00000518659 / NM_001122679.2; = p.R1501C on NM_001080428.3) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1280634774, COSV69129323; called by muse, mutect2, varscan2
- TEX15 | c.6397T>C p.S2133P (on ENST00000256246; = p.S2516P on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99821246; called by muse, mutect2, varscan2
- TFPI2 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs751463825, COSV55989782; called by muse, mutect2, varscan2
- TGIF1 | c.82C>T p.Q28* (on ENST00000330513 / NM_001374396.1; = p.Q48* on NM_003244.4) | Nonsense Mutation (SNP) | VAF 26/103 reads (25%) | catalogued as COSV100394820; called by muse, mutect2, varscan2
- THAP2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs183448616, COSV57349426; called by muse, mutect2, varscan2
- THOC1 | c.144del p.K48Nfs*12 | Frame Shift Del (DEL) | VAF 98/301 reads (33%) | catalogued as rs746975641; called by mutect2, varscan2
- THRAP3 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 46/156 reads (29%) | catalogued as COSV63566841; called by muse, mutect2
- TIAM1 | c.3882C>T p.F1294= | Splice Region (SNP) | VAF 52/178 reads (29%) | catalogued as rs567504389, COSV54577078; called by muse, mutect2, varscan2
- TIE1 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.964); catalogued as rs750816125, COSV65249726; called by muse, mutect2, varscan2
- TKTL2 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs770403160, COSV99761350; called by muse, mutect2, varscan2
- TLCD3B | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1178436191, COSV99662407; called by muse, mutect2, varscan2
- TLK1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 258/874 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62629019; called by muse, mutect2, varscan2
- TMCO3 | c.487C>A p.Q163K | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV100952316; called by muse, mutect2, varscan2
- TMCO3 | c.1709C>T p.T570M | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs142314118; called by muse, mutect2, varscan2
- TMEM131 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs1325780555, COSV51786738; called by muse, mutect2, varscan2
- TMEM132B | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100169505; called by muse, mutect2, varscan2
- TMEM176B | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99133687; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 66/176 reads (38%) | catalogued as rs770800449; called by mutect2, varscan2
- TMPRSS15 | c.1451del p.N484Tfs*4 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | catalogued as COSV99518561; called by pindel, varscan2
- TMPRSS6 | c.1507G>T p.G503W | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV100695708; called by muse, mutect2, varscan2
- TMTC3 | c.2274del p.K758Nfs*31 | Frame Shift Del (DEL) | VAF 29/137 reads (21%) | catalogued as rs1304750530; called by pindel, varscan2*
- TMX1 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100790055; called by muse, mutect2, varscan2
- TNC | c.6218G>A p.R2073Q | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764464070, COSV100405627; called by muse, mutect2, varscan2
- TNFRSF9 | c.346+2T>C p.X116_splice | Splice Site (SNP) | VAF 29/128 reads (23%) | catalogued as COSV101097236; called by muse, mutect2, varscan2
- TOP1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 139/316 reads (44%) | catalogued as COSV100793798; called by muse, mutect2, varscan2
- TOR1A | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as rs755593280, COSV61029362; called by muse, mutect2, varscan2
- TP53BP2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776842497, COSV100636599; called by muse, mutect2, varscan2
- TPX2 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV55921034; called by muse, mutect2
- TRAM1L1 | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs1560751500, COSV100162171; called by muse, mutect2, varscan2
- TRIM46 | c.2152dup p.L718Pfs*28 | Frame Shift Ins (INS) | VAF 72/279 reads (26%) | catalogued as rs1198297200; called by mutect2, pindel, varscan2
- TRPA1 | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100084012; called by muse, mutect2, varscan2
- TRPV2 | c.2215C>A p.L739M | Missense Mutation (SNP) | VAF 71/198 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.146); catalogued as COSV100641192; called by muse, mutect2, varscan2
- TSFM | c.685C>T p.P229S (on ENST00000323833 / NM_001172696.2; = p.P208S on NM_005726.6) | Missense Mutation (SNP) | VAF 73/328 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as COSV99142337; called by muse, mutect2, varscan2
- TSLP | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 37/168 reads (22%) | catalogued as COSV61291672; called by muse, mutect2, varscan2
- TTC3 | c.5436G>T p.Q1812H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as COSV100695409; called by mutect2, varscan2
- TTC37 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 60/194 reads (31%) | catalogued as COSV100706581; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTK | c.1743C>A p.H581Q | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100036232; called by muse, mutect2, varscan2
- TTLL11 | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100388705; called by muse, mutect2, varscan2
- TTN | c.71164C>T p.R23722C (on ENST00000591111; = p.R16298C on NM_003319.4) | Missense Mutation (SNP) | VAF 36/84 reads (43%) | PolyPhen probably damaging (0.917); catalogued as rs757511354, COSV100607532, COSV59879663, COSV60124163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.5889del p.V1964Wfs*14 (on ENST00000591111; = p.V1918Wfs*14 on NM_003319.4) | Frame Shift Del (DEL) | VAF 70/252 reads (28%) | catalogued as rs34700943; called by mutect2, pindel, varscan2
- TUB | c.812G>A p.R271Q (on ENST00000299506 / NM_177972.3; = p.R326Q on NM_003320.4) | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV55109558; called by muse, mutect2, varscan2
- TUBA3C | c.800T>C p.F267S | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101262785; called by mutect2, varscan2
- TUBA3E | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); catalogued as COSV99919911; called by muse, mutect2, varscan2
- TUBA3E | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.013); catalogued as rs780831143, COSV56058185; called by muse, mutect2, varscan2
- TUBB2A | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 80/262 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.093); catalogued as COSV61319458; called by muse, mutect2, varscan2
- TULP4 | c.1792C>T p.Q598* | Nonsense Mutation (SNP) | VAF 59/224 reads (26%) | catalogued as COSV100893438; called by muse, mutect2, varscan2
- TWNK | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs1400893442, COSV99272344; called by muse, mutect2, varscan2
- UBN2 | c.2506C>T p.H836Y | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV99943877; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3835C>T p.Q1279* | Nonsense Mutation (SNP) | VAF 67/346 reads (19%) | catalogued as rs961000680, COSV99691519; called by muse, mutect2, varscan2
- UNC13C | c.3861G>T p.W1287C | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99516232; called by muse, varscan2
- UNC79 | c.4972G>T p.G1658C (on ENST00000393151 / NM_001346218.2; = p.G1481C on NM_020818.5) | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV99827535; called by muse, mutect2, varscan2
- UPF1 | c.854T>C p.V285A | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs756721195, COSV99439490; called by muse, mutect2, varscan2
- UPK2 | c.150del p.C51Vfs*10 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs750952264; called by mutect2, pindel, varscan2
- UPK3A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs188696049, COSV99343118; called by muse, mutect2, varscan2
- USP15 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV99739347; called by muse, mutect2, varscan2
- USP24 | c.2711C>T p.A904V | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.956); catalogued as COSV53771989; called by muse, mutect2, varscan2
- USP32 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs962576565, COSV100341893; called by muse, mutect2, varscan2
- USP45 | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as COSV100569623; called by muse, mutect2, varscan2
- USP49 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as rs755973085, COSV99790154; called by muse, varscan2
- UTP3 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 85/307 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747804289, COSV54660870; called by muse, mutect2, varscan2
- UTP6 | c.202A>T p.I68F | Missense Mutation (SNP) | VAF 64/319 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99911919; called by muse, mutect2, varscan2
- VEPH1 | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100747520; called by muse, mutect2, varscan2
- VLDLR | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV101173222; called by muse, mutect2, varscan2
- VPS13D | c.7829A>G p.D2610G | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99166312; called by muse, mutect2, varscan2
- VPS33A | c.1057A>G p.N353D | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.079); catalogued as COSV99931334; called by muse, mutect2, varscan2
- VWA2 | c.1997G>T p.G666V | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.221); catalogued as COSV100073548; called by muse, mutect2, varscan2
- WDR26 | c.1046G>A p.R349H (on ENST00000414423 / NM_001379403.1; = p.R249H on NM_025160.7) | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs772952060, COSV54355453; called by muse, mutect2, varscan2
- WDR43 | c.1722_1724del p.L575del | In Frame Del (DEL) | VAF 14/66 reads (21%) | catalogued as rs1264002274; called by pindel, varscan2
- WDR45 | c.596C>A p.S199Y (on ENST00000376372 / NM_001029896.2; = p.S200Y on NM_007075.3) | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV100540238, COSV59875868; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 70/256 reads (27%) | catalogued as rs746919573; called by mutect2, varscan2
- WDR72 | c.3021A>G p.I1007M | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as COSV100854404, COSV64753225; called by muse, mutect2, varscan2
- WNK1 | c.1316T>C p.V439A | Missense Mutation (SNP) | VAF 118/248 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100267197; called by muse, mutect2, varscan2
- WNK1 | c.1476_1478del p.E492del | In Frame Del (DEL) | VAF 134/345 reads (39%) | catalogued as rs1402275718; called by pindel, varscan2
- XDH | c.3235G>A p.A1079T | Missense Mutation (SNP) | VAF 101/302 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1331025827, COSV101052183; called by muse, mutect2, varscan2
- XIRP1 | c.3402del p.W1135Gfs*2 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | catalogued as rs1166941994; called by mutect2, pindel, varscan2
- XKR8 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1339161578, COSV100871945; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | catalogued as rs779864368; called by mutect2, pindel
- ZBED1 | c.2041G>A p.V681I | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs781624072, COSV58131798; called by muse, mutect2, varscan2
- ZBTB20 | c.1940G>T p.S647I (on ENST00000474710 / NM_001164342.2; = p.S574I on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/235 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100613671; called by muse, mutect2, varscan2
- ZBTB41 | c.1478G>A p.C493Y | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100963070; called by muse, mutect2, varscan2
- ZC3H4 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756950439, COSV53410194; called by muse, mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 62/208 reads (30%) | catalogued as rs745875253; called by mutect2, varscan2
- ZER1 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs760146636, COSV99401873; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs141273536; called by muse, varscan2
- ZNF19 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as rs17857322, COSV99867284; called by muse, mutect2, varscan2
- ZNF211 | c.1331G>A p.R444Q (on ENST00000347302 / NM_198855.4; = p.R457Q on NM_006385.5) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs191091619, COSV53745419; called by muse, mutect2, varscan2
- ZNF236 | c.3422A>G p.Q1141R | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs761465193, COSV99470225; called by muse, varscan2
- ZNF285 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs773215916, COSV100449973; called by muse, mutect2, varscan2
- ZNF318 | c.4733A>G p.K1578R | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.488); catalogued as COSV100546138; called by muse, mutect2, varscan2
- ZNF337 | c.1900G>T p.G634W | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99430160; called by muse, mutect2, varscan2
- ZNF385D | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1034519990, COSV55752967; called by muse, mutect2, varscan2
- ZNF438 | c.2101T>A p.W701R | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV100061770; called by muse, mutect2, varscan2
- ZNF446 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs1179649890, COSV100236199; called by muse, mutect2, varscan2
- ZNF451 | c.1910G>C p.S637T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.084); catalogued as COSV100674873; called by muse, mutect2, varscan2
- ZNF454 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV100194864; called by muse, mutect2, varscan2
- ZNF474 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1228133450, COSV56948168; called by muse, mutect2, varscan2
- ZNF551 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.081); catalogued as COSV99989946; called by muse, varscan2
- ZNF557 | c.1185del p.K395Nfs*40 (on ENST00000414706 / NM_001044388.2; = p.K402Nfs*40 on NM_024341.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 48/170 reads (28%) | catalogued as rs759839287; called by mutect2, varscan2
444 further variants in this file (172 protein-altering or splice-affecting, 247 silent, 25 other) are not listed here.
